Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1MQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1MQ-01A (Primary Tumor).

105-0-3

Carcinoma, Squamous cell, Nos 8070/3
Site: cervix, Nos C53.9 2/24/11

Patient Name: [REDACTED]

DOB: [REDACTED]

MRN: [REDACTED]

Patient ID: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

* Consult Report *

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Inside/Outside

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS

CERVIX, BIOPSY

- INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment:

Sections show sheets and poorly formed cords of enlarged, pleomorphic cells. Mitotic figures and apoptotic bodies are abundant. Necrosis is present. Focal definitive keratinization is seen.

History:

The patient is a [REDACTED] year old woman with a history of HSIL on Pap smear and severe dysplasia.

Materials Received:

Received is one slide labeled [REDACTED] accompanied by a corresponding pathology report. The material originates from [REDACTED]. Digitally scanned and saved for our files.

Source: NCI Genomic Data Commons file 0f768173-93ed-4b57-8dd2-4639caff5e4b (TCGA-C5-A1MQ.C77E58E6-6536-4DBE-9703-8EA34A3C908B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).